Somatic mutation profile of tumor specimen TCGA-AG-3725-01A (aliquot TCGA-AG-3725-01A-11D-1733-10) from TCGA case TCGA-AG-3725, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage III; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AG-3725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9817db6-2cfd-4261-a0f3-20b0232ee635.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3725-11A (Solid Tissue Normal), aliquot TCGA-AG-3725-11A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d509d9d2-606a-4f08-86d7-3ba731eecd57

The open-access MAF lists 94 somatic variants for this specimen: 77 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 16, Nonsense Mutation 7, Splice Site 2, Frame Shift Del 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as rs121913462, CM077502, COSV57322511, COSV57366061, COSV57375983; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1099C>T p.R367* (on ENST00000281708 / NM_001349798.2; = p.R287* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 115/254 reads (45%) | hotspot (GDC flag); catalogued as COSV55891887; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 88/103 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/39 reads (82%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACKR3 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs777382973, COSV56023782; called by muse, mutect2, varscan2
- ACOXL | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV67738728; called by muse, mutect2, varscan2
- ADRA1D | c.705G>T p.W235C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65242180; called by muse, mutect2, varscan2
- ALDH1A1 | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52794795; called by muse, mutect2, varscan2
- ANKS1A | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147778746, COSV64459999; called by muse, mutect2, varscan2
- APCDD1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.479); catalogued as rs201834801; called by muse, mutect2, varscan2
- ATP6V0A2 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57752744; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.75); catalogued as rs757399634, COSV59481222; called by muse, mutect2, varscan2
- BCL9 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99324793; called by muse, mutect2
- BGN | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1156728437, COSV59036355; called by muse, mutect2, varscan2
- C19orf18 | c.428G>T p.R143M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1459990050, COSV58708295; called by muse, mutect2, varscan2
- CACNA1H | c.5521G>A p.V1841M | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370975488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAVIN1 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146596349, COSV63812879; called by muse, mutect2, varscan2
- CC2D2B | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373755580; called by muse, mutect2, varscan2
- CCKBR | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747024445, COSV58106455; called by muse, mutect2, varscan2
- CDHR5 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755331585, COSV62764032; called by mutect2, varscan2
- CES1 | c.904-1G>T p.X302_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as rs140353865, COSV62086187, COSV62090788; called by muse, mutect2, varscan2
- COL1A1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56810155; called by muse, mutect2, varscan2
- CRX | c.581C>G p.T194S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV55760295; called by muse, mutect2, varscan2
- DAAM2 | c.3193C>T p.R1065W (on ENST00000274867 / NM_001201427.2; = p.R1064W on NM_015345.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as rs775538347, COSV51347996; called by muse, mutect2, varscan2
- DBR1 | c.1561C>G p.Q521E | Missense Mutation (SNP) | VAF 127/485 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs752311275, COSV53429544, COSV53431371; called by muse, mutect2, varscan2
- DCDC1 | c.3202A>G p.I1068V (on ENST00000597505 / NM_001367979.1; = p.I175V on NM_020869.3) | Missense Mutation (SNP) | VAF 139/244 reads (57%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV60313796; called by muse, mutect2, varscan2
- DNAH8 | c.12677A>C p.E4226A | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV100544109; called by muse, mutect2
- DOCK10 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776429569, COSV51430080; called by muse, mutect2, varscan2
- DOCK4 | c.4360C>T p.R1454C | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs1191592349, COSV70244094; called by muse, mutect2, varscan2
- EFHC2 | c.935A>T p.K312M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV69555792; called by muse, mutect2, varscan2
- FCN1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs199652976, COSV65662993; called by muse, mutect2, varscan2
- FKBP6 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV99333866; called by muse, mutect2, varscan2
- FLRT2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs140606612; called by muse, mutect2, varscan2
- FRZB | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1415736303, COSV54553283; called by muse, mutect2, varscan2
- GPR32 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs750570773, COSV54514022; called by muse, varscan2
- ITGA8 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747010112, COSV65237255; called by muse, mutect2, varscan2
- ITGAV | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 67/78 reads (86%) | catalogued as COSV53719943; called by muse, mutect2, varscan2
- ITGBL1 | c.320A>G p.H107R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101095244, COSV66012561; called by muse, mutect2, varscan2
- KIR2DL3 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100667699; called by muse, mutect2
- LMNTD1 | c.785T>A p.L262* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as COSV51451274; called by muse, mutect2
- LPA | c.4700C>T p.P1567L | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1230957395, COSV60313901; called by muse, mutect2, varscan2
- MAP3K21 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779367692, COSV64043697; called by muse, mutect2, varscan2
- MYH4 | c.2813C>A p.A938D | Missense Mutation (SNP) | VAF 181/462 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV55114583; called by muse, mutect2, varscan2
- NAP1L3 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV59077988; called by muse, mutect2
- NFATC4 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1399617431, COSV51613047; called by muse, mutect2, varscan2
- NID1 | c.3623-2A>C p.X1208_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99937268; called by muse, mutect2
- NRXN1 | c.3138A>T p.K1046N | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV58499097; called by muse, mutect2, varscan2
- NUP160 | c.2488G>C p.V830L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV65856380; called by muse, mutect2, varscan2
- OR1L4 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 158/342 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753520295, COSV52340369; called by muse, mutect2, varscan2
- OTOGL | c.3965C>T p.A1322V (on ENST00000547103; = p.A1313V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV72008066; called by muse, mutect2, varscan2
- PCDHA11 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.356); catalogued as COSV56551689; called by muse, mutect2, varscan2
- PDPK1 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs753410336, COSV51914871; called by muse, mutect2, varscan2
- PEG3 | c.2543A>G p.N848S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs750731373, COSV55649943, COSV99687894; called by muse, mutect2, varscan2
- PLPP7 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV64836263; called by muse, mutect2, varscan2
- PLXNA1 | c.3276C>T p.N1092= | Splice Region (SNP) | VAF 34/38 reads (89%) | catalogued as rs368234275; called by muse, mutect2, varscan2
- POLR1G | c.544del p.T182Qfs*10 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV50005688; called by mutect2, pindel
- PRAMEF19 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879225837; called by muse, varscan2
- RELN | c.1247T>C p.I416T | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV59037668; called by muse, mutect2, varscan2
- RHOJ | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs921202045, COSV57456941; called by muse, mutect2, varscan2
- RPRD1A | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs781199117, COSV59823569; called by muse, mutect2, varscan2
- SFMBT2 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1415368617, COSV100738725; called by muse, mutect2, varscan2
- SGMS1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.739); catalogued as rs1564869339, COSV62373764; called by muse, mutect2, varscan2
- SIGLEC8 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs757220139, COSV58476177; called by muse, mutect2, varscan2
- SIN3A | c.3418C>T p.R1140* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV64585354; called by muse, mutect2, varscan2
- SLITRK1 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65677912; called by muse, mutect2, varscan2
- STAT2 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 44/86 reads (51%) | catalogued as COSV100028737; called by muse, mutect2, varscan2
- TBC1D8B | c.2327T>C p.L776P | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs745400775, COSV99344121; called by muse, mutect2, varscan2
- TENM2 | c.2309G>T p.C770F (on ENST00000518659 / NM_001122679.2; = p.C538F on NM_001080428.3) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69143679; called by muse, mutect2, varscan2
- TFAP2C | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205025811, COSV52373507; called by muse, mutect2, varscan2
- TLE6 | c.1267G>A p.G423R (on ENST00000246112 / NM_001143986.2; = p.G300R on NM_024760.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55738212; called by muse, mutect2, varscan2
- TNNT1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1166914763, COSV52573950; called by muse, mutect2, varscan2
- UBE2E2 | c.330T>G p.F110L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV59980396; called by muse, mutect2, varscan2
- UTP14C | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101584265; called by muse, mutect2
- VPS52 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69385457; called by muse, mutect2, varscan2
- YLPM1 | c.2908G>C p.A970P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53121999; called by muse, mutect2, varscan2
- DTWD1 | c.754_763del p.E252Tfs*5 | Frame Shift Del (DEL) | VAF 57/161 reads (35%) | called by mutect2, pindel, varscan2
- AASS | c.2565G>A p.T855= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs1487551370, COSV62790569; called by muse, mutect2, varscan2
- ACTL7B | c.738C>T p.D246= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65928268, COSV65928383; called by muse, mutect2
- ANKH | c.717C>T p.S239= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52487373; called by muse, mutect2, varscan2
- CATIP | c.99C>T p.I33= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV56824661; called by muse, mutect2, varscan2
- COQ3 | c.201C>A p.I67= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1469222261, COSV54642426, COSV99632720; called by muse, mutect2, varscan2
- ENTPD7 | c.528C>A p.G176= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV65113420; called by muse, mutect2, varscan2
- F8 | c.2991T>C p.A997= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV100811396; called by muse, mutect2, varscan2
- FILIP1 | c.513G>A p.L171= | Silent (SNP) | VAF 67/149 reads (45%) | catalogued as COSV52742163; called by muse, mutect2, varscan2
- HIVEP2 | c.5145C>T p.T1715= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs753009520, COSV50005469; called by muse, mutect2, varscan2
- NALCN | c.4623C>T p.S1541= | Silent (SNP) | VAF 69/81 reads (85%) | catalogued as rs138902474; called by muse, mutect2, varscan2
- PCDHA2 | c.2193G>A p.A731= | Silent (SNP) | VAF 76/115 reads (66%) | catalogued as rs1554120315, COSV65365667; called by muse, mutect2, varscan2
- PLEKHN1 | c.1500G>A p.S500= (on ENST00000379409; = p.S448= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs149795372; called by muse, mutect2, varscan2
- THSD7B | c.1281G>A p.T427= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as rs563732139, COSV55693111, COSV99760095; called by muse, mutect2, varscan2
- TNXB | c.7233C>T p.Y2411= (on ENST00000647633; = p.Y2164= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1333951751, COSV64487916; called by muse, mutect2, varscan2
- ZFHX4 | c.351C>T p.S117= | Silent (SNP) | VAF 79/97 reads (81%) | catalogued as rs183191105, COSV51500042; called by muse, mutect2, varscan2
- ZIC3 | c.786C>T p.S262= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV54976552, COSV99799641; called by muse, varscan2
- BCL7A | c.561+45G>A | Intron (SNP) | VAF 15/38 reads (39%) | catalogued as COSV55850582; called by muse, mutect2, varscan2
